CCDI case PBBIUC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/81bd8008-3d87-4d2d-9fac-71dfa1d39603

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.8 years (1,762 days).

Biospecimens (3 samples)
- Sample 0D9S2X: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0D9S3C: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0D9S44: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
